Surgical pathology report (de-identified scan), TCGA case TCGA-N7-A4Y5, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site Washington University, specimen TCGA-N7-A4Y5-01A (Primary Tumor).

[page 1 of 3]
Patient Name: [REDACTED]

Surgical Pathology Report

Final

SURGICAL PATHOLOGY REPORT FINAL

Patient Name: [REDACTED]

Address: [REDACTED]

Gender: F

Service: [REDACTED]

Location: [REDACTED]

MRN: [REDACTED]

Hospital #: [REDACTED]

Patient Type: [REDACTED]

Accession

Taken:

Received:

Accessioned:

Reported:

Physician(s):

Other Related Clinical Data:
DIAGNOSIS:

- UTERUS, "PROLAPSED CERVICAL TUMOR," EXCISION (FS1)
- MALIGNANT MIXED MULLERIAN TUMOR (SEE COMMENT)
- UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY
- MALIGNANT MIXED MULLERIAN TUMOR WITH HETEROLOGOUS ELEMENTS
- TUMOR EXTENSIVELY INVOLVES THE LOWER UTERINE SEGMENT
- UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY
- MALIGNANT MIXED MULLERIAN TUMOR BY DIRECT EXTENSION, INVOLVING THE FULL THICKNESS OF THE MYOMETRIUM
- LEIOMYOMATA
- UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY
- NO HISTOPATHOLOGIC ABNORMALITY
- OVARIES, RIGHT AND LEFT, BILATERAL SALPINGO-OOPHORECTOMY
- NO HISTOPATHOLOGIC ABNORMALITY
- FALLOPIAN TUBES, RIGHT AND LEFT, BILATERAL SALPINGO-OOPHORECTOMY
- NO HISTOPATHOLOGIC ABNORMALITY
- VAGINA, EXCISION
- METASTATIC MALIGNANT MIXED MULLERIAN TUMOR (SEE COMMENT)
- OMENTUM, OMENTECTOMY
- METASTATIC MALIGNANT MIXED MULLERIAN TUMOR

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By

Intraoperative Consultation:

An intraoperative non-microscopic consultation was obtained and interpreted as:
"Called to pick up 'uterus, cervix,' consisting of an 8 x 6.5 x 6 cm, 238 gram

*ICD-6-3
Carcinoma / Mixed Mullerian
Tumor, malignant 8950/3
Site: Corpus Uteri, Endometrium
C54.1
JH 3/28/13*

[page 2 of 3]
Patient Name: [REDACTED]

uterus. The surgeon indicated that no cervix was identified. The bilateral ovaries and fallopian tubes are identified (left fallopian tube = 8.3 cm, left ovary = 2 x 1 x 0.8 cm, right fallopian tube = 5 x 0.3 cm, and right ovary = 2 x 1.5 x 0.9 cm). Opened to show a polypoid, tan-white mass. No identifiable endomyometrium seen. Tumor tissue for . Rest for permanents," by

FS: Cervix, "polypoid cervical tumor," excision
- "Poorly differentiated malignant neoplasm, favor sarcoma or sarcomatoid component of malignant mixed Mullerian tumor,"

Microscopic Description and Comment:

Sections of the material labeled "prolapsed cervical tumor" show fragments of mixed mullerian tumor. No definitive cervical tissue is identified in the multiple sections examined.

Sections of the vagina show metastatic malignant mixed Mullerian tumor; in this location, the tumor shows a predominance of sarcomatoid elements. The cervix tissue included in the specimen shows no definitive involvement by tumor. Sections of the omentum show metastatic malignant mixed Mullerian tumor; in this location, the tumor shows a predominant glandular pattern. (

History:

The patient is an year old woman with a prolapsed, pedunculated cervical mass. Operative procedure: Total abdominal hysterectomy with bilateral salpingo-oophorectomy.

Specimen(s) Received:

- A: CERVICAL TUMOR
- B: UTERUS AND CERVIX
- C: VAGINA
- D: OMENTUM

Gross Description

The specimens are received in four formalin-filled containers each labeled "[REDACTED]". The first container is labeled "prolapsed cervical tumor, FS1." It contains a white cassette that holds two fragments of tan-green to tan-white tissue, each measuring, 1.8 x 1 x 0.4 cm. Labeled A1 (FS1). Also in the container is a piece of tan-brown to tan-pink tissue, measuring 4.5 x 4 x 1 cm. Sectioning shows a tan-brown to tan-white cut surface. Labeled A2 to A4. Jar

1. The second container is labeled "uterus and cervix." It contains a previously opened, 238 gram uterus with bilateral adnexae measuring 8 x 6.5 x 6 cm. The serosa is tan-brown, smooth and shiny, and appears nodular. No definitive ectocervix is identified anteriorly. The anterior resection margin is inked blue. Posteriorly, there is a strip of tan-white, smooth ectocervix, measuring 7 x 1.5 cm. The entire endometrial cavity is replaced by a tan-yellow, fleshy friable, polypoid mass, measuring 6 x 6 x 5 cm. Sectioning the anterior and posterior myometrium shows calcified leiomyomata, ranging from 1.5 cm x 1.5 cm to 0.5 cm x 0.5 cm. The tan-white corrugated right ovary measures 2 x 1.5 x 0.9 cm. Sectioning shows a tan-white to tan-brown, unremarkable cut surface. The right fallopian tube measures 5 x 0.3 cm. The serosa is tan-purple and smooth. Sectioning shows a tan-white wall with a pinpoint, unremarkable lumen. The tan-white, corrugated left ovary measures 2 x 1 x 0.8 cm. Sectioning shows a tan-white, cystic cut surface. The left fallopian tube measures 8 x 0.3 cm. The serosa is tan-purple and smooth. Sectioning shows a tan-white wall with a pinpoint, unremarkable lumen. Also in the container are multiple tan-white to

[page 3 of 3]
Patient Name: [REDACTED]

tan-purple, friable, necrotic masses of tissue, measuring in aggregate, 15 x 9 x 7 cm. Sectioning shows a tan-white cut surface. Anterior contiguous strips; B1, B2 - anterior resection margin and putative endocervix; B3, B4 - lower uterine segment and tumor; B5, B6 - anterior fundus with tumor. Posterior contiguous strips; B7 - posterior ectocervix; B8 - posterior lower uterine segment; B9, B10 - posterior fundus with tumor; B12 - tumor; B13 to B16 - necrotic tissue (random sections); B17, B18 - additional superficial tumor; B19 - left

ovary and fallopian tube; B20 - right ovary and fallopian tube. Jar 2.

The third container is labeled "anterior vagina." It contains a piece of tan-white to tan-brown tissue measuring 3 x 2 x 0.8 cm. One side is lined by a tan-white, smooth epithelium; the opposite appears tan-pink and has a putative mucosal surface. Inked blue. No os is identified. Labeled C1 to C5. Jar 0.

The fourth container is labeled "omentum." It contains a piece of fibrofatty tissue measuring 20 x 10 x 3 cm. Sectioning shows a tan-yellow cut surface. No focal masses or lesions are identified. Labeled D1 to D5. Jar 2.

SYNOPTIC REPORTING FORM FOR MALIGNANT ENDOMETRIAL TUMORS

HISTOPATHOLOGIC TYPE

The histologic diagnosis is malignant mixed mullerian tumor with heterologous stromal elements

TUMOR INVASION

Invasive tumor is present with invasion of the outer 1/3 of the myometrium

ENDOCERVICAL INVOLVEMENT

The endocervix is not involved by tumor

LYMPHVASCULAR SPACE INVASION

Lymphovascular space invasion by tumor is present but limited in scope

REGIONAL LYMPH NODES (N)

Regional lymph nodes cannot be assessed (NX)

DISTANT METASTASIS (M)

Distant metastasis cannot be assessed (MX)

PRIMARY TUMOR (TNM Category/FIGO Stage)

Vaginal involvement (direct extension or metastasis) (T3b/IIIB)

STAGE GROUPING

T3B/NX/MX (Stage X)

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

HPAAs discrepancy		✓
Prior to the Primary History		✓
Dual/Simultaneous Primary Noted		✓
Case is [REDACTED]		
Reviewed by [REDACTED]		
Date Reviewed [REDACTED]		

lw 2/7/13

Source: NCI Genomic Data Commons file a6fd7ec5-735c-4dee-b5b6-727a4524830c (TCGA-N7-A4Y5.0C2C2709-04EB-4872-AF03-9CE87E9DD22C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).